Gene-level copy-number profile of tumor specimen TCGA-39-5011-01A from TCGA case TCGA-39-5011, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-39-5011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d0d4db12-5c6f-46d8-8c93-86968c379f21.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5011-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6336fe54-e707-4f77-88eb-65d060272dcd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 1,672; copy number 2: 27,574; copy number 3: 15,142; copy number 4: 11,750; copy number 5: 1,758; copy number 6: 857; copy number 8: 566; copy number 10: 166; copy number 11: 68; copy number 12: 18; copy number 14: 33; copy number 15: 77; copy number 16: 6; copy number 21: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5011-01A-01D-1439-01): tumor purity 0.43, ploidy 1.57, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,700,595–9,442,380, 7 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr9:102,256,604–102,657,514, 4 genes (within-gene range 0–5): RNU6-329P, AL442644.2, AL442644.1, LINC00587.
- chr10:87,503,881–89,414,557, 48 genes (within-gene range 0–2): MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,606 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–28,287,807, 429 genes, copy number 5–8 (broad region; genes not listed).
- chr5:57,081,745–69,595,221, 172 genes, copy number 5–8 (broad region; genes not listed).
- chr7:79,452,877–127,253,093, 741 genes, copy number 8–21 (within-gene range 4–21) (broad region; genes not listed).
- chr7:127,997,597–128,862,626, 44 genes, copy number 10: SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP, AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3, FAM71F2, AC018638.6, IMP3P2, RNA5SP242, RNA5SP243, FAM71F1, CALU, RN7SL81P, OPN1SW, CCDC136, FLNC, FLNC-AS1.
- chr7:134,816,543–137,182,107, 35 genes, copy number 6–11 (within-gene range 4–11): AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51.
- chr7:139,561,570–140,722,790, 23 genes, copy number 10 (within-gene range 4–10): HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1.
- chr7:145,675,679–148,420,998, 9 genes, copy number 5 (within-gene range 3–5): AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr8:111,621,458–145,066,685, 522 genes, copy number 5 (broad region; genes not listed).
- chr9:102,611,162–138,203,325, 798 genes, copy number 5 (broad region; genes not listed).
- chr11:112,787,304–135,075,908, 526 genes, copy number 6 (broad region; genes not listed).
- chr18:21,981,121–33,441,101, 178 genes, copy number 5–14 (broad region; genes not listed).
- chr18:37,960,220–37,992,413, 1 gene, copy number 8: AC108452.1.
- chr18:47,912,207–48,410,752, 6 genes, copy number 5 (within-gene range 2–5): AC120349.2, ZBTB7C, AC105101.1, AC105101.2, RNU6-708P, C18orf12.
- chr20:20,389,530–22,746,991, 45 genes, copy number 5: RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1, AL109807.1, LINC01432, AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3.
- chr20:23,772,785–24,446,314, 13 genes, copy number 5: CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53.
- chr20:30,323,367–32,439,319, 64 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 58. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
